TCGA case TCGA-MH-A856 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6c15b31b-6942-43a9-b698-701a61430e30

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.8 years (20,006 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T1a; AJCC clinical N: NX; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 947 days (2.6 years).
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 1.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 541 days (1.5 years); Disease response: Tumor Free.
- Days to follow up: 947 days (2.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Platelets: Normal.
- Leukocytes: Elevated.
- Hemoglobin: Normal.
- Lactate Dehydrogenase: Normal.
- Calcium: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73.3 kg; Height: 177.8 cm; BMI: 23.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 15; Tobacco smoking onset year: 1982; Tobacco smoking quit year: 2012.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MH-A856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-MH-A856-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample TCGA-MH-A856-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MH-A856-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: No; Tobacco smoking history indicator: 4; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 947 days; disease-specific survival: no event (censored), 947 days; disease-free interval: no event (censored), 947 days; progression-free interval: no event (censored), 947 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MH-A856-01A-11D-A34Y-01): tumor purity 0.79, ploidy 2.02, whole-genome doublings 0.
